Somatic mutation profile of tumor specimen TCGA-JW-A5VI-01A (aliquot TCGA-JW-A5VI-01A-11D-A28B-09) from TCGA case TCGA-JW-A5VI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 45.0 years (16,444 days).
Specimen TCGA-JW-A5VI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b5f24be-665c-4b8b-baaf-5121c01050cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JW-A5VI-10A (Blood Derived Normal), aliquot TCGA-JW-A5VI-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/950580f6-63e9-4678-b5db-5fc1f660c6c9

The open-access MAF lists 75 somatic variants for this specimen: 62 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 12, Nonsense Mutation 6, Splice Site 4, Frame Shift Ins 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 23/79 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV63309258, COSV63309273, COSV63309318; called by muse, mutect2, varscan2
- ACTR2 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV53199099; called by muse, mutect2, varscan2
- ADH6 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV52954792, COSV52955036; called by muse, mutect2, varscan2
- ANAPC7 | c.1042C>G p.H348D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.564); catalogued as COSV71443658; called by muse, mutect2, varscan2
- ARID2 | c.3926C>G p.S1309* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV57594609; called by muse, mutect2, varscan2
- ARID2 | c.4174C>G p.P1392A | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.138); catalogued as COSV57594619; called by muse, mutect2, varscan2
- ATF7IP | c.2710C>T p.R904* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs1283765821, COSV53765658; called by muse, mutect2, varscan2
- ATG9B | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.047); catalogued as COSV52501809; called by muse, mutect2, varscan2
- BATF | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs1273785872, COSV54375188; called by muse, mutect2, varscan2
- CACNA2D1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); catalogued as rs1416010629, COSV62375073; called by muse, mutect2, varscan2
- CALN1 | c.586G>A p.A196T (on ENST00000329008 / NM_001017440.3; = p.A238T on NM_031468.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770151080, COSV61117552; called by muse, mutect2, varscan2
- CARM1 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV58998676; called by muse, mutect2, varscan2
- CEP162 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as COSV57616853; called by muse, mutect2, varscan2
- COL5A3 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 91/143 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs773722641, COSV53405282; called by muse, mutect2, varscan2
- DACT1 | c.2471G>A p.R824H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770244112, COSV60019206, COSV60023634; called by muse, mutect2, varscan2
- DNAAF1 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as rs1435223373, COSV57576238; called by muse, mutect2, varscan2
- DSCAM | c.3050T>C p.I1017T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV68019992; called by muse, mutect2, varscan2
- EIF4A1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99548946; called by muse, mutect2, varscan2
- EPHA5 | c.3073G>C p.E1025Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as COSV56628249, COSV56674137; called by muse, mutect2, varscan2
- FASTK | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs374560885, COSV52538920; called by muse, mutect2, varscan2
- FBXO41 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as COSV54581520; called by muse, mutect2, varscan2
- GALC | c.442+2T>C p.X148_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as COSV54322704; called by muse, mutect2, varscan2
- GBA3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV72438338; called by muse, mutect2, varscan2
- GPC5 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs138581416; called by muse, mutect2, varscan2
- GRXCR1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs142351714, COSV67670862, COSV67672841; called by muse, mutect2, varscan2
- HSD17B4 | c.489G>A p.M163I (on ENST00000414835 / NM_001199291.3; = p.M138I on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV56333200; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs758456769; called by muse, mutect2, varscan2
- IL16 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as COSV57259693; called by muse, mutect2, varscan2
- JMJD1C | c.5862+1G>C p.X1954_splice | Splice Site (SNP) | VAF 13/52 reads (25%) | catalogued as COSV59512383; called by muse, mutect2, varscan2
- KAT6A | c.2477C>G p.S826C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs778735235, COSV55901923; called by muse, mutect2, varscan2
- LMBRD1 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV65296056; called by muse, mutect2, varscan2
- LYSMD4 | c.731C>A p.A244D (on ENST00000409796 / NM_001284417.2; = p.A245D on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV100230611; called by muse, mutect2
- MAN2B2 | c.925A>T p.I309F | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53450218; called by muse, mutect2, varscan2
- MTTP | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV55503520; called by muse, mutect2, varscan2
- MUS81 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs753816989, COSV57258765; called by muse, mutect2, varscan2
- NOVA1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV57471490; called by muse, mutect2, varscan2
- OFD1 | c.1817C>G p.S606* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV60793888; called by muse, mutect2, varscan2
- PEAR1 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV52770511; called by muse, mutect2, varscan2
- PLEKHG4 | c.3454+1G>T p.X1152_splice | Splice Site (SNP) | VAF 15/49 reads (31%) | catalogued as COSV58570899; called by muse, mutect2, varscan2
- PRDM9 | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as COSV57001826, COSV57006155, COSV57009770; called by muse, mutect2, varscan2
- PSMB9 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1248539990, COSV62753658; called by muse, mutect2, varscan2
- PTPN13 | c.1681C>G p.L561V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.625); catalogued as COSV57401693; called by muse, mutect2, varscan2
- RBFOX1 | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV60943308; called by muse, mutect2, varscan2
- RSPH10B2 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs778831805, COSV51867471; called by mutect2, varscan2
- SLC1A2 | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53518290; called by muse, mutect2, varscan2
- SLC25A16 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.047); catalogued as COSV56263722, COSV99770293; called by muse, mutect2, varscan2
- SLC25A47 | c.144+1G>A p.X48_splice | Splice Site (SNP) | VAF 26/69 reads (38%) | catalogued as rs367820954, COSV100836458, COSV64161427; called by muse, mutect2, varscan2
- SLC46A2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT tolerated (0.27); PolyPhen benign (0.133); catalogued as COSV65289475; called by muse, mutect2, varscan2
- SLC7A2 | c.205G>A p.V69M (on ENST00000494857 / NM_001370338.1; = p.V109M on NM_003046.6) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs761652013, COSV50247412; called by muse, mutect2, varscan2
- SMARCC2 | c.3220G>A p.A1074T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.173); catalogued as COSV53236984; called by muse, mutect2, varscan2
- SOHLH2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs772136308, COSV65900912; called by muse, mutect2, varscan2
- SYNE1 | c.24556G>T p.E8186* (on ENST00000367255 / NM_182961.4; = p.E8115* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 29/97 reads (30%) | catalogued as COSV54896068; called by muse, mutect2
- THAP9 | c.1905G>C p.Q635H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56355507; called by muse, mutect2, varscan2
- THSD7B | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.072); catalogued as rs746519581, COSV55649390; called by muse, mutect2, varscan2
- TKTL2 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV54917156, COSV54919380; called by muse, mutect2, varscan2
- TPCN2 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs755078998, COSV53726733; called by muse, mutect2, varscan2
- UBXN4 | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as COSV55633126; called by muse, mutect2, varscan2
- ZNF526 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as COSV55898352; called by muse, mutect2
- ZNF714 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as COSV52509377; called by muse, mutect2, varscan2
- HELT | c.210dup p.P71Sfs*130 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | called by pindel, varscan2
- OR6C2 | c.662_673del p.R221_L224del | In Frame Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- ZNF791 | c.110dup p.K38Qfs*16 | Frame Shift Ins (INS) | VAF 39/83 reads (47%) | called by mutect2, pindel, varscan2
- DNAH8 | c.6807C>T p.L2269= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV59421726; called by muse, mutect2, varscan2
- MYO15A | c.1281C>T p.H427= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV52751087; called by muse, mutect2, varscan2
- PCDH1 | c.3237C>T p.L1079= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs781624054, COSV54610498; called by muse, mutect2, varscan2
- PCDHB8 | c.1344C>T p.N448= | Silent (SNP) | VAF 47/88 reads (53%) | catalogued as rs1554281186, COSV50753525; called by muse, mutect2, varscan2
- PHKA2 | c.477C>T p.L159= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs187396860, COSV101177049; called by muse, mutect2, varscan2
- RABIF | c.24C>T p.S8= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs142176614, COSV66126905; called by muse, mutect2
- SCN7A | c.549C>T p.L183= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs376920778; called by muse, mutect2, varscan2
- SH3BP2 | c.861C>T p.T287= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs376641544; called by muse, mutect2, varscan2
- SMO | c.777G>A p.S259= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs373730958; called by muse, mutect2, varscan2
- TMC5 | c.604C>T p.L202= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV66864213; called by muse, mutect2, varscan2
- VKORC1L1 | c.429C>T p.I143= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs958347131, COSV62488170; called by muse, mutect2, varscan2
- ZNF672 | c.1308C>T p.L436= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs1224279762, COSV60637124; called by muse, mutect2, varscan2
- DCHS2 | n.8702C>T | RNA (SNP) | VAF 23/87 reads (26%) | catalogued as COSV61767408; called by muse, mutect2, varscan2
